CPTAC case C3L-07437 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/905abef2-91b3-4148-9f9e-8c229d51ceea

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1946; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Hematopoietic system, NOS; Age at diagnosis: 75.1 years (27,419 days); Year of diagnosis: 2021; Days to last known disease status: 1,193 days (3.3 years); Progression or recurrence: no; Days to last follow up: 1,193 days (3.3 years); Calgb risk group: Intermediate/Normal.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Stem Cell Transplantation, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (3 entries)
- Days to follow up: 386 days (1.1 years); Karnofsky performance status: 70; ECOG performance status: 1.
- Days to follow up: 710 days (1.9 years); Karnofsky performance status: 70; ECOG performance status: 1.
- Days to follow up: 1,193 days (3.3 years); Karnofsky performance status: 70; ECOG performance status: 1.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Non-Drinker.

Biospecimens (5 samples)
- Samples C3L-07437-50, C3L-07437-51, C3L-07437-52 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-07437-55, C3L-07437-56 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw; Diagnosis pathologically confirmed: Yes.
